Somatic mutation profile of tumor specimen C3L-09808-02 (aliquot CPT0541610009) from CPTAC case C3L-09808, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 74.6 years (27,231 days).
Specimen C3L-09808-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ae993fe-1108-4bef-9c32-34334391a7a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09808-31 (Blood Derived Normal), aliquot CPT0541750004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/227c6d4d-2674-4bc5-97e3-7599e5cd1d37

The open-access MAF lists 1,941 somatic variants for this specimen: 1,448 protein-altering or splice-affecting, 410 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 954, Silent 410, Frame Shift Del 253, Frame Shift Ins 174, Intron 53, Nonsense Mutation 32, Splice Region 13, 3'UTR 12, Splice Site 12, 5'Flank 7, In Frame Del 6, 3'Flank 5.

Variants (750 of 1,941; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC5 | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 153/673 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777662, CM145974; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLPB | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 43/412 reads (10%) | catalogued as rs185461628; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DLD | c.633dup p.V212Sfs*32 | Frame Shift Ins (INS) | VAF 31/160 reads (19%) | catalogued as rs1040811473; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- GALK1 | c.410del p.G137Vfs*27 | Frame Shift Del (DEL) | VAF 45/326 reads (14%) | catalogued as rs767329054, CD993840; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MLH1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs63751711, CM045463, CM082944, CS951471, CS961616, COSV51619014; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NBN | c.1651dup p.R551Kfs*5 | Frame Shift Ins (INS) | VAF 38/226 reads (17%) | catalogued as rs766044684; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 27/153 reads (18%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 25/160 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 47/162 reads (29%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TCF4 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 22/166 reads (13%) | catalogued as rs121909122, CM072074; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WNK2 | c.4912dup p.D1638Gfs*9 (on ENST00000297954 / NM_001282394.1; = p.D1601Gfs*9 on NM_006648.3) | Frame Shift Ins (INS) | VAF 124/688 reads (18%) | catalogued as rs757473977; ClinVar: likely pathogenic; called by mutect2, varscan2
- ABCA5 | c.4676G>A p.R1559H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs148561229, COSV67019234; called by muse, mutect2, varscan2
- ABCC3 | c.1622G>A p.C541Y | Missense Mutation (SNP) | VAF 135/562 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV53323816; called by muse, mutect2, varscan2
- ABCD4 | c.1361A>G p.H454R | Missense Mutation (SNP) | VAF 77/329 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as rs776556552; called by muse, mutect2, varscan2
- ABHD18 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1186504338, COSV66294266; called by muse, mutect2, varscan2
- ABL1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 89/453 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as rs772834697; called by muse, mutect2, varscan2
- AC011005.1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 70/629 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1310867814, COSV71955946; called by muse, mutect2, varscan2
- AC093512.2 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 91/385 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); catalogued as rs1355782850; called by muse, mutect2, varscan2
- ACAD9 | c.456G>A p.G152= | Splice Region (SNP) | VAF 22/274 reads (8%) | catalogued as rs755199331; called by muse, mutect2
- ACP6 | c.1056G>A p.W352* | Nonsense Mutation (SNP) | VAF 67/331 reads (20%) | catalogued as COSV100984273; called by muse, mutect2, varscan2
- ACTN4 | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs1420356916; called by muse, mutect2, varscan2
- ACTRT1 | c.149G>T p.R50I | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs772248403, COSV100947591; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 49/146 reads (34%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS10 | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 73/372 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54356296; called by muse, mutect2, varscan2
- ADAMTS13 | c.3446G>A p.R1149Q | Missense Mutation (SNP) | VAF 137/859 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782472825; called by muse, mutect2, varscan2
- ADAMTS9 | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265031681, COSV55779734; called by muse, mutect2, varscan2
- ADAP1 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 108/574 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs769198805; called by muse, mutect2, varscan2
- ADCY6 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 101/413 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57169457; called by muse, mutect2, varscan2
- ADGRB2 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 138/623 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1280323359; called by muse, mutect2, varscan2
- AFDN | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60038131; called by muse, mutect2, varscan2
- AGBL1 | c.2720A>C p.K907T | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV66868237; called by muse, mutect2
- AGBL2 | c.2414del p.L805Yfs*3 | Frame Shift Del (DEL) | VAF 46/278 reads (17%) | catalogued as COSV104405789; called by mutect2, pindel, varscan2
- AGPAT4 | c.907dup p.R303Pfs*60 | Frame Shift Ins (INS) | VAF 80/409 reads (20%) | catalogued as rs750826126; called by mutect2, varscan2
- ALDH3B2 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 64/309 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0.251); catalogued as COSV62427924; called by muse, mutect2, varscan2
- ANGEL1 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.097); catalogued as rs760066871, COSV51871936; called by muse, mutect2, varscan2
- ANGPTL2 | c.209G>A p.C70Y | Missense Mutation (SNP) | VAF 70/408 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52233827; called by muse, mutect2, varscan2
- ANKK1 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 96/541 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs763284159, COSV100392876; called by muse, mutect2, varscan2
- ANKRD11 | c.6793G>A p.A2265T | Missense Mutation (SNP) | VAF 146/662 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.028); catalogued as rs1567554892, COSV56365045; called by mutect2, varscan2
- ANKRD12 | c.2804del p.N935Ifs*24 | Frame Shift Del (DEL) | VAF 36/135 reads (27%) | catalogued as rs868780344; called by mutect2, varscan2
- ANKRD12 | c.3291dup p.H1098Tfs*2 | Frame Shift Ins (INS) | VAF 26/171 reads (15%) | catalogued as rs1449847635; called by mutect2, pindel, varscan2
- ANKRD31 | c.2149G>A p.V717I | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs992244667; called by muse, mutect2, varscan2
- AP2A2 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 125/533 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59961912; called by muse, mutect2, varscan2
- APBA3 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 122/657 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766776005; called by muse, mutect2, varscan2
- APBB1IP | c.1799del p.P600Rfs*56 | Frame Shift Del (DEL) | VAF 52/188 reads (28%) | catalogued as rs1314335534; called by mutect2, pindel, varscan2
- ARAP1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 98/410 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.167); catalogued as COSV61989144; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 31/175 reads (18%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP10 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as rs768626844; called by muse, mutect2, varscan2
- ARHGAP30 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 64/282 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV63516492; called by muse, mutect2, varscan2
- ARHGAP35 | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 64/291 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as COSV101351030; called by muse, mutect2, varscan2
- ARHGEF25 | c.92dup p.R32Tfs*2 | Frame Shift Ins (INS) | VAF 50/220 reads (23%) | catalogued as rs748506876; called by mutect2, varscan2
- ARHGEF26 | c.1090del p.M364Cfs*2 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | catalogued as rs772560852; called by pindel, varscan2
- ARID1A | c.3961_3963del p.P1321del | In Frame Del (DEL) | VAF 77/418 reads (18%) | catalogued as rs1285505074; called by pindel, varscan2
- ASAP2 | c.2357dup p.L787Afs*16 | Frame Shift Ins (INS) | VAF 77/413 reads (19%) | catalogued as rs773893016; called by mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 33/188 reads (18%) | catalogued as rs1558707706; called by mutect2, pindel, varscan2
- ATG9B | c.293dup p.T99Nfs*50 | Frame Shift Ins (INS) | VAF 65/467 reads (14%) | catalogued as rs770350293; called by mutect2, varscan2
- ATRIP | c.290dup p.N97Kfs*13 | Frame Shift Ins (INS) | VAF 24/144 reads (17%) | catalogued as rs1454682560; called by mutect2, pindel, varscan2
- ATXN7L1 | c.1790C>T p.T597I | Missense Mutation (SNP) | VAF 117/567 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV66301023; called by muse, mutect2, varscan2
- AUTS2 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 58/397 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs777962059, COSV61421405; called by muse, mutect2, varscan2
- AXIN1 | c.1116+1G>A p.X372_splice | Splice Site (SNP) | VAF 52/209 reads (25%) | catalogued as COSV51984731; called by muse, varscan2
- AZIN2 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as rs139641288, COSV99613470; called by muse, mutect2, varscan2
- BAG1 | c.107del p.P36Rfs*37 | Frame Shift Del (DEL) | VAF 114/734 reads (16%) | catalogued as rs1229767469; called by pindel, varscan2
- BAP1 | c.79del p.V27Cfs*45 | Frame Shift Del (DEL) | VAF 62/334 reads (19%) | catalogued as CD1212544, CD134972; called by mutect2, pindel, varscan2
- BBS9 | c.1582A>G p.R528G (on ENST00000242067 / NM_001348036.1; = p.R488G on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs775178031; called by muse, mutect2, varscan2
- BCAR1 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 115/514 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs780049900; called by muse, mutect2, varscan2
- BCAS2 | c.293dup p.N98Kfs*2 | Frame Shift Ins (INS) | VAF 36/184 reads (20%) | catalogued as rs750058115; called by mutect2, varscan2
- BCL9L | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 111/605 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs375800295; called by muse, mutect2, varscan2
- BCORL1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 90/399 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1403214128, COSV99500222; called by muse, mutect2, varscan2
- BEST3 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.108); catalogued as rs372783693; called by muse, mutect2, varscan2
- BIN1 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 73/346 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs758360325, COSV99035052; called by muse, mutect2, varscan2
- BIRC7 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 77/426 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs893292012; called by muse, mutect2, varscan2
- BLM | c.2268del p.D757Tfs*4 | Frame Shift Del (DEL) | VAF 19/134 reads (14%) | catalogued as rs747341586; called by mutect2, pindel, varscan2
- BNC1 | c.2470A>G p.T824A | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV61757443; called by muse, mutect2, varscan2
- BRAT1 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 92/522 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751548415; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 69/332 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1483781735, COSV54588044; called by muse, mutect2, varscan2
- BUD13 | c.1471_1472dup p.D491Efs*26 | Frame Shift Ins (INS) | VAF 40/219 reads (18%) | catalogued as rs755085427; called by mutect2, varscan2
- BX255925.3 | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 137/714 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.143); catalogued as rs1444436526; called by muse, mutect2, varscan2
- C12orf57 | c.107T>C p.M36T | Missense Mutation (SNP) | VAF 97/414 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs1555146012; called by muse, mutect2, varscan2
- C12orf60 | c.435A>T p.K145N | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); catalogued as rs1376696078; called by muse, mutect2, varscan2
- C18orf32 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs766028505; called by muse, mutect2, varscan2
- C3orf49 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs765302572; called by muse, mutect2, varscan2
- C4orf50 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 123/564 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.631); catalogued as rs1241454068; called by muse, mutect2, varscan2
- C7orf50 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.75); catalogued as COSV62476494; called by muse, mutect2
- CACNA1B | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 70/617 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV53134658, COSV53152028; called by muse, mutect2, varscan2
- CACNA1G | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 106/440 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as rs1468956826; called by muse, mutect2, varscan2
- CACTIN | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs745952291, COSV99028224; called by muse, mutect2
- CALR3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs766005088; called by muse, mutect2, varscan2
- CALY | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 102/368 reads (28%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs1362719178; called by muse, varscan2
- CAMK2A | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62247124; called by muse, mutect2, varscan2
- CAMSAP3 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 123/550 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1341043357; called by muse, mutect2, varscan2
- CAMSAP3 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 101/516 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs549080555, COSV50332923; called by muse, mutect2, varscan2
- CAPN11 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755910697; called by muse, varscan2
- CAPN5 | c.499C>T p.R167C (on ENST00000456580; = p.R127C on NM_004055.5) | Missense Mutation (SNP) | VAF 106/476 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as rs559189456, COSV53687927; called by muse, mutect2, varscan2
- CARD14 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 75/330 reads (23%) | catalogued as rs367867373; called by muse, mutect2, varscan2
- CARMIL2 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 63/285 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1428762094, COSV100575957; called by muse, mutect2, varscan2
- CASK | c.2470C>T p.R824W (on ENST00000378163 / NM_001367721.1; = p.R819W on NM_003688.3) | Missense Mutation (SNP) | VAF 93/462 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369792621, CM148711, COSV59363352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CATSPER2 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV58660453; called by muse, mutect2, varscan2
- CATSPERZ | c.458T>C p.M153T | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs202192649; called by muse, mutect2, varscan2
- CC2D2B | c.2241G>T p.Q747H | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1020022280; called by muse, mutect2, varscan2
- CCDC124 | c.140T>C p.M47T | Missense Mutation (SNP) | VAF 38/425 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs1400760223; called by muse, mutect2
- CCDC141 | c.4504T>C p.C1502R | Missense Mutation (SNP) | VAF 74/293 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV55371641; called by muse, mutect2, varscan2
- CCDC166 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 151/787 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV101545826; called by muse, mutect2, varscan2
- CCDC171 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as rs1057209618, COSV52639464; called by muse, mutect2, varscan2
- CCNL2 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 100/459 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs879009298; called by muse, mutect2, varscan2
- CCNY | c.681G>T p.W227C | Missense Mutation (SNP) | VAF 61/309 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55185223; called by muse, varscan2
- CCT7 | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV57822851; called by muse, mutect2, varscan2
- CD22 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 73/369 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as rs781725931, COSV50049779; called by muse, mutect2, varscan2
- CD274 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV67501360; called by muse, mutect2, varscan2
- CD68 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 230/515 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs531445203, COSV51511957; called by muse, mutect2, varscan2
- CD93 | c.1702G>A p.V568M | Missense Mutation (SNP) | VAF 24/594 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs891369060, COSV55665567; called by muse, mutect2
- CDC45 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 71/338 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs767498757, COSV99596343; called by muse, mutect2, varscan2
- CDK20 | c.955del p.H319Tfs*16 (on ENST00000325303 / NM_001039803.3; = p.H298Tfs*16 on NM_012119.4) | Frame Shift Del (DEL) | VAF 105/622 reads (17%) | catalogued as rs749463697; called by mutect2, pindel, varscan2
- CDK5RAP2 | c.4879del p.A1627Qfs*50 | Frame Shift Del (DEL) | VAF 87/569 reads (15%) | catalogued as rs1564177048; called by mutect2, pindel, varscan2
- CEBPZ | c.128A>G p.E43G | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs1170251854; called by muse, mutect2, varscan2
- CELSR1 | c.6689A>G p.N2230S | Missense Mutation (SNP) | VAF 108/545 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.609); catalogued as rs1242569962; called by muse, mutect2, varscan2
- CELSR3 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 135/584 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953849009, COSV99375576; called by muse, mutect2, varscan2
- CFAP65 | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 115/517 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs769586505, COSV58559280; called by muse, mutect2, varscan2
- CFAP69 | c.2745del p.K915Nfs*12 | Frame Shift Del (DEL) | VAF 52/299 reads (17%) | catalogued as COSV100290203; called by mutect2, pindel, varscan2
- CFAP92 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs775502593, COSV99415046; called by muse, mutect2, varscan2
- CFAP97D2 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs746658769; called by mutect2, varscan2
- CFH | c.773C>A p.P258Q | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as CM070668, COSV62776315; called by muse, mutect2, varscan2
- CHP1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 27/365 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs79101281, COSV58156679; called by muse, mutect2
- CHRDL1 | c.680G>A p.G227E (on ENST00000372045; = p.G233E on NM_145234.4) | Missense Mutation (SNP) | VAF 76/402 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs1286952146; called by muse, mutect2, varscan2
- CHST2 | c.723dup p.R242Afs*92 | Frame Shift Ins (INS) | VAF 141/598 reads (24%) | catalogued as rs766570662; called by mutect2, pindel, varscan2
- CHSY3 | c.559C>A p.R187S | Missense Mutation (SNP) | VAF 132/621 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59276606; called by muse, mutect2, varscan2
- CHTF18 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 113/562 reads (20%) | catalogued as rs373611090; called by muse, mutect2, varscan2
- CIBAR2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 74/335 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.552); catalogued as rs1257262261, COSV73320677; called by muse, mutect2, varscan2
- CILP2 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 84/419 reads (20%) | catalogued as rs754649866, COSV52279833; called by muse, mutect2, varscan2
- CLCN4 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 101/504 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101073949; called by muse, mutect2, varscan2
- CLCNKB | c.1334_1335del p.S445Ffs*5 | Frame Shift Del (DEL) | VAF 26/172 reads (15%) | catalogued as rs1380983236; called by pindel, varscan2
- CLDN10 | c.219C>T p.D73= | Splice Region (SNP) | VAF 62/286 reads (22%) | catalogued as rs1010607066, COSV54824823, COSV54825684; called by muse, mutect2, varscan2
- CLDN9 | c.537del p.L180Sfs*196 | Frame Shift Del (DEL) | VAF 114/578 reads (20%) | catalogued as rs763852712; called by mutect2, pindel, varscan2
- CLEC14A | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 131/538 reads (24%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.65); catalogued as rs768322288; called by muse, mutect2, varscan2
- CLIC5 | c.989C>T p.S330F (on ENST00000185206 / NM_001370649.1; = p.S171F on NM_016929.5) | Missense Mutation (SNP) | VAF 81/346 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764132378; called by muse, mutect2, varscan2
- CNGB1 | c.1942A>G p.I648V | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV99201419; called by muse, mutect2, varscan2
- CNTN6 | c.314T>G p.L105R | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV63164865, COSV63182098; called by muse, mutect2, varscan2
- COBLL1 | c.151G>A p.A51T (on ENST00000392717; = p.A13T on NM_014900.5) | Missense Mutation (SNP) | VAF 103/491 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs567043601; called by muse, mutect2, varscan2
- COL16A1 | c.3862G>A p.G1288S | Missense Mutation (SNP) | VAF 72/345 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1043007813, COSV99595543; called by muse, mutect2, varscan2
- COL1A2 | c.2120C>A p.P707H | Missense Mutation (SNP) | VAF 58/422 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV51965953; called by muse, mutect2, varscan2
- COL22A1 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs150603745; called by muse, mutect2, varscan2
- COL28A1 | c.2105G>C p.G702A | Missense Mutation (SNP) | VAF 67/395 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751573664, COSV68083013; called by muse, mutect2, varscan2
- COL6A5 | c.7736A>G p.E2579G (on ENST00000312481; = p.E2575G on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99592044; called by muse, mutect2, varscan2
- COPA | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 47/195 reads (24%) | catalogued as COSV54099440; called by muse, mutect2, varscan2
- CPAMD8 | c.2216C>T p.T739M (on ENST00000651564; = p.T692M on NM_015692.5) | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs753298491, COSV52232485; called by muse, mutect2, varscan2
- CPD | c.81C>A p.S27R | Missense Mutation (SNP) | VAF 41/620 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.009); catalogued as COSV99853061; called by muse, mutect2
- CPEB1 | c.1297C>T p.R433* (on ENST00000617958; = p.R368* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 65/293 reads (22%) | catalogued as COSV55622379; called by muse, mutect2, varscan2
- CPLANE1 | c.263G>A p.R88Q (on ENST00000425232; = p.R160Q on NM_023073.3) | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.105); catalogued as rs766961442; called by muse, mutect2, varscan2
- CPPED1 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs761272120; called by muse, mutect2, varscan2
- CPTP | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 128/549 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs377587453; called by muse, mutect2, varscan2
- CRACD | c.2866C>T p.P956S | Missense Mutation (SNP) | VAF 97/488 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.148); catalogued as rs758298598; called by muse, mutect2, varscan2
- CRTAC1 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 116/490 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769753665, COSV54003405; called by muse, varscan2
- CSK | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.527); catalogued as rs754136671, COSV54974351; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 34/164 reads (21%) | catalogued as rs766438669; called by mutect2, varscan2
- CST1 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 34/232 reads (15%) | catalogued as rs756924682; called by mutect2, varscan2
- CTNNA2 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.908); catalogued as rs1395041551; called by muse, mutect2, varscan2
- CTTNBP2 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs753418523, COSV99354919; called by muse, varscan2
- CUBN | c.8281G>T p.G2761* | Nonsense Mutation (SNP) | VAF 41/239 reads (17%) | catalogued as COSV100912457; called by muse, mutect2, varscan2
- CXorf38 | c.427A>G p.N143D | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV59948093; called by muse, mutect2, varscan2
- CYFIP2 | c.3299G>A p.R1100H (on ENST00000616178 / NM_001291722.2; = p.R1075H on NM_014376.4) | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV59033324; called by muse, mutect2, varscan2
- CYP1B1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 111/552 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs104894978, CM104163, COSV99572835; ClinVar: not provided; called by muse, mutect2, varscan2
- CYP4B1 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 65/365 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs557491224; called by muse, mutect2, varscan2
- DAPK1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 60/396 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.092); catalogued as rs548113187, COSV63783988; called by muse, mutect2, varscan2
- DCAF12L2 | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 97/537 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs1326781748, COSV63584562; called by muse, mutect2, varscan2
- DDI1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 76/465 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs779548652, COSV56371148; called by muse, mutect2, varscan2
- DDR2 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs754868982, COSV63370876; called by muse, mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | catalogued as rs772416332; called by mutect2, varscan2
- DECR1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 68/440 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1396472988; called by muse, mutect2, varscan2
- DENND11 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 94/661 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1407945406; called by muse, mutect2, varscan2
- DENND2A | c.2801G>A p.R934H | Missense Mutation (SNP) | VAF 78/470 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs376717563; called by muse, mutect2, varscan2
- DENND2C | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs757669631; called by muse, mutect2, varscan2
- DERPC | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.943); catalogued as rs1434956115; called by muse, mutect2, varscan2
- DHDDS | c.517dup p.V173Gfs*10 | Frame Shift Ins (INS) | VAF 106/360 reads (29%) | catalogued as rs1272594778; called by mutect2, varscan2
- DIS3L2 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342603922, COSV56065391; called by muse, mutect2, varscan2
- DLG3 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 108/608 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs984580660; called by muse, varscan2
- DLGAP2 | c.393del p.R132Afs*15 | Frame Shift Del (DEL) | VAF 151/818 reads (18%) | catalogued as rs755665055, COSV101422687, COSV70099967; called by mutect2, varscan2
- DMAC2L | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780854333; called by muse, mutect2, varscan2
- DMTN | c.281dup p.P95Tfs*38 | Frame Shift Ins (INS) | VAF 66/488 reads (14%) | catalogued as rs772208110; called by mutect2, varscan2
- DNAH10 | c.5089C>T p.R1697C (on ENST00000409039; = p.R1636C on NM_207437.3) | Missense Mutation (SNP) | VAF 23/552 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1159136067, COSV68991212; called by muse, mutect2
- DNAH11 | c.7394C>T p.A2465V | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs1262698407, COSV60950297; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAJA4 | c.1187C>T p.T396M (on ENST00000343789; = p.T425M on NM_018602.3) | Missense Mutation (SNP) | VAF 67/288 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs199879308; called by muse, mutect2, varscan2
- DNMT3B | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs113400552, COSV52415819; called by muse, mutect2
- DOCK6 | c.5561C>T p.T1854M | Missense Mutation (SNP) | VAF 100/534 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777898007; called by muse, varscan2
- DOCK8 | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs765616150; called by muse, mutect2, varscan2
- DPP6 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs1396638241; called by muse, varscan2
- DPP6 | c.2324G>A p.R775Q (on ENST00000377770 / NM_001364500.2; = p.R713Q on NM_001936.5) | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs774600621, COSV59614658; called by muse, mutect2, varscan2
- DPP7 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 77/404 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1285637872; called by muse, mutect2, varscan2
- DRD2 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 61/294 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs772612900, COSV60759413; called by muse, mutect2, varscan2
- DUOXA2 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 62/484 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV50995367; called by muse, mutect2, varscan2
- DUS1L | c.1343C>A p.P448H | Missense Mutation (SNP) | VAF 86/362 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs1284920605; called by muse, mutect2, varscan2
- DUS3L | c.717del p.T240Hfs*46 | Frame Shift Del (DEL) | VAF 115/585 reads (20%) | catalogued as rs1568388323; called by mutect2, pindel, varscan2
- DYNC2H1 | c.9011G>A p.R3004H | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755871858; called by muse, mutect2, varscan2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | catalogued as rs751377941; called by mutect2, varscan2
- E2F1 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 78/359 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); catalogued as rs1160676980; called by muse, mutect2, varscan2
- EDNRB | c.295G>A p.G99R (on ENST00000377211 / NM_001201397.1; = p.G9R on NM_000115.5) | Missense Mutation (SNP) | VAF 21/577 reads (4%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as COSV100526552; called by muse, mutect2
- EHD1 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 174/628 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV57733710; called by muse, mutect2, varscan2
- EHD2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 133/582 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV54409205; called by muse, mutect2, varscan2
- EHD4 | c.1045T>C p.Y349H | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767520779; called by muse, mutect2, varscan2
- EIF2AK4 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 132/564 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.187); catalogued as rs866960579; called by muse, mutect2, varscan2
- EMILIN2 | c.2887_2888del p.D963Rfs*72 | Frame Shift Del (DEL) | VAF 74/416 reads (18%) | catalogued as rs1277037398; called by pindel, varscan2
- ENO4 | c.1029del p.H345Tfs*21 (on ENST00000622726; = p.H342Tfs*21 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 46/221 reads (21%) | catalogued as rs1156693659; called by mutect2, varscan2
- ENPP6 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 82/388 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749863026, COSV57067709; called by muse, varscan2
- ENTPD7 | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 61/309 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs767625155, COSV65112500; called by muse, mutect2, varscan2
- EPHB6 | c.165+1dup | Frame Shift Ins (INS) | VAF 82/398 reads (21%) | catalogued as rs771807343; called by mutect2, varscan2
- EPM2AIP1 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 49/472 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs771405339, COSV99212424; called by muse, mutect2, varscan2
- EPPK1 | c.3599G>A p.R1200Q | Missense Mutation (SNP) | VAF 116/701 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs558373320, COSV73261078; called by muse, mutect2, varscan2
- ERCC4 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as rs373565480; called by muse, mutect2, varscan2
- ERFE | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 156/660 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.254); catalogued as rs1013793071; called by muse, varscan2
- EVPL | c.4589G>A p.R1530H | Missense Mutation (SNP) | VAF 135/547 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.226); catalogued as rs1295563040, COSV56909740; called by muse, mutect2, varscan2
- EXO1 | c.864del p.F288Lfs*11 | Frame Shift Del (DEL) | VAF 34/224 reads (15%) | catalogued as COSV100799586; called by mutect2, pindel, varscan2
- EXOC8 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 151/668 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs1282964961; called by muse, mutect2, varscan2
- FAM170B | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 104/513 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs866081998, COSV61253791, COSV61254220; called by muse, mutect2, varscan2
- FAM189A1 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 108/470 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1225675427; called by muse, mutect2, varscan2
- FAM214A | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1300265233; called by muse, mutect2, varscan2
- FAM83H | c.2787del p.V930Cfs*44 | Frame Shift Del (DEL) | VAF 137/820 reads (17%) | catalogued as COSV62029432; called by mutect2, pindel, varscan2
- FBN1 | c.7760del p.G2587Afs*95 | Frame Shift Del (DEL) | VAF 63/293 reads (22%) | catalogued as CD152333; called by mutect2, pindel, varscan2
- FBN2 | c.3145G>A p.E1049K | Missense Mutation (SNP) | VAF 27/414 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs771853346, COSV99327635; ClinVar: uncertain significance; called by muse, mutect2
- FBXL7 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 103/529 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1330246214, COSV61644173; called by muse, mutect2, varscan2
- FBXO25 | c.962G>A p.R321Q (on ENST00000382824 / NM_183421.2; = p.R254Q on NM_012173.3) | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV52337123; called by muse, mutect2, varscan2
- FEZ2 | c.938del p.N313Tfs*12 | Frame Shift Del (DEL) | VAF 34/146 reads (23%) | catalogued as rs759258050; called by mutect2, varscan2
- FEZ2 | c.166_168del p.E56del | In Frame Del (DEL) | VAF 114/562 reads (20%) | catalogued as rs1157210515; called by pindel, varscan2
- FGA | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.106); catalogued as rs780354544; called by muse, mutect2, varscan2
- FLRT2 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs754917817, COSV58139180; called by muse, mutect2, varscan2
- FMNL3 | c.45dup p.S16Lfs*15 | Frame Shift Ins (INS) | VAF 93/470 reads (20%) | catalogued as rs1423125806; called by mutect2, pindel, varscan2
- FMO3 | c.1186A>G p.T396A | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1274839305; called by muse, mutect2, varscan2
- FOLH1 | c.1609T>C p.Y537H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs764896694; called by muse, mutect2, varscan2
- FPR1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 70/318 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as rs147646924; called by muse, mutect2, varscan2
- FREM2 | c.6403C>T p.R2135* | Nonsense Mutation (SNP) | VAF 45/171 reads (26%) | catalogued as rs759639276; called by muse, mutect2, varscan2
- FREM3 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs1304474624; called by muse, mutect2, varscan2
- FRMD3 | c.978del p.F326Lfs*44 | Frame Shift Del (DEL) | VAF 27/262 reads (10%) | catalogued as rs1341565999; called by mutect2, pindel, varscan2
- FRMD4A | c.2770G>A p.V924I | Missense Mutation (SNP) | VAF 83/600 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as rs779709485, COSV62264208; called by muse, mutect2, varscan2
- FTCD | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 96/484 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs1208719468, COSV52426624; called by muse, varscan2
- FZD10 | c.1677dup p.A560Sfs*13 | Frame Shift Ins (INS) | VAF 69/351 reads (20%) | catalogued as rs1294762337; called by mutect2, pindel, varscan2
- FZR1 | c.69C>T p.R23= | Splice Region (SNP) | VAF 72/361 reads (20%) | catalogued as rs371487179; called by muse, mutect2, varscan2
- GABRB1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 119/495 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs78133797, COSV54991113; called by muse, mutect2, varscan2
- GABRP | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1336167569, COSV54662954; called by muse, mutect2
- GALNT11 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs763185697; called by muse, mutect2, varscan2
- GALR1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 56/478 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.046); catalogued as rs756079511, COSV55316467; called by muse, mutect2, varscan2
- GAPVD1 | c.1456A>C p.S486R | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52928321; called by muse, mutect2, varscan2
- GAS2L1 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 139/560 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs1488127764; called by muse, mutect2, varscan2
- GCK | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 67/377 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs754479025, COSV61754462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCNT1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 44/303 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs142199715; called by muse, mutect2, varscan2
- GFOD1 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 102/504 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV64954995; called by muse, varscan2
- GFRA1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 105/399 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs1254072073, COSV62602193; called by muse, mutect2, varscan2
- GIGYF1 | c.2635C>T p.R879C | Missense Mutation (SNP) | VAF 102/525 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs764497122; called by muse, mutect2, varscan2
- GLI1 | c.671_672dup p.E225Rfs*56 | Frame Shift Ins (INS) | VAF 56/283 reads (20%) | catalogued as rs1566559797; called by mutect2, varscan2
- GLMP | c.1142dup p.G382Rfs*37 | Frame Shift Ins (INS) | VAF 103/523 reads (20%) | catalogued as rs1482027421; called by mutect2, pindel, varscan2
- GNA15 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775221783; called by muse, mutect2, varscan2
- GNL3 | c.1021C>A p.L341I | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); catalogued as COSV56477518; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 66/286 reads (23%) | catalogued as rs763679060; called by mutect2, varscan2
- GOLPH3 | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs760560885, COSV54059724; called by muse, mutect2, varscan2
- GP5 | c.230A>G p.Q77R | Missense Mutation (SNP) | VAF 103/446 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV99756317; called by muse, mutect2, varscan2
- GPR135 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 71/581 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.094); catalogued as rs1566551076; called by muse, mutect2, varscan2
- GPR19 | c.1202dup p.L402Afs*6 | Frame Shift Ins (INS) | VAF 35/212 reads (17%) | catalogued as rs1566129610; called by mutect2, varscan2
- GREM1 | c.104del p.P35Rfs*49 | Frame Shift Del (DEL) | VAF 110/596 reads (18%) | catalogued as COSV55715863; called by mutect2, pindel, varscan2
- GRHL3 | c.1736del p.P579Hfs*11 | Frame Shift Del (DEL) | VAF 49/317 reads (15%) | catalogued as rs1207812332; called by mutect2, pindel, varscan2
- GRINA | c.72dup p.P25Afs*102 | Frame Shift Ins (INS) | VAF 56/355 reads (16%) | catalogued as rs781965675; called by mutect2, varscan2
- GRM5 | c.2926G>A p.A976T (on ENST00000305447 / NM_001143831.2; = p.A944T on NM_000842.4) | Missense Mutation (SNP) | VAF 127/536 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1237525518; called by muse, mutect2, varscan2
- GRM6 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 113/570 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.875); catalogued as rs778651919; called by muse, mutect2, varscan2
- H3C10 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 93/444 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as COSV60797424; called by muse, mutect2, varscan2
- HAUS1 | c.52dup p.I18Nfs*11 | Frame Shift Ins (INS) | VAF 28/135 reads (21%) | catalogued as rs751752301; called by mutect2, varscan2
- HAUS7 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 118/504 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); catalogued as rs782121459; called by muse, mutect2, varscan2
- HERC2 | c.9793G>A p.G3265R | Missense Mutation (SNP) | VAF 95/500 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1375387386; called by muse, mutect2, varscan2
- HK3 | c.896T>C p.L299P | Missense Mutation (SNP) | VAF 71/331 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99457531; called by muse, mutect2, varscan2
- HMGXB3 | c.4459C>A p.R1487S (on ENST00000613459; = p.R1241S on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/375 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53827968; called by muse, mutect2, varscan2
- HMMR | c.127A>G p.R43G | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs1419072413; called by muse, mutect2, varscan2
- HMX1 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 139/619 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs1216328036; called by muse, mutect2, varscan2
- HMX3 | c.68del p.P23Hfs*100 | Frame Shift Del (DEL) | VAF 59/268 reads (22%) | catalogued as rs779589617; called by mutect2, varscan2
- HOATZ | c.62del p.P21Rfs*79 | Frame Shift Del (DEL) | VAF 74/289 reads (26%) | catalogued as rs570525399; called by mutect2, varscan2
- HOXC12 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 114/578 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as rs143550250; called by muse, mutect2, varscan2
- HOXD3 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 119/558 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.186); catalogued as COSV50882430; called by muse, mutect2, varscan2
- HPCA | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 97/464 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV61276396; called by muse, mutect2, varscan2
- HS3ST4 | c.1338T>G p.D446E | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV58809436, COSV58824064; called by muse, mutect2, varscan2
- HSPB9 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 92/430 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs782722556, COSV56791413; called by muse, mutect2, varscan2
- HYDIN | c.8096G>A p.R2699H | Missense Mutation (SNP) | VAF 73/345 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs368332616; called by muse, mutect2, varscan2
- ID4 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs1212595694, COSV66342813; called by muse, mutect2, varscan2
- IGF2 | c.452C>T p.S151L (on ENST00000434045 / NM_001127598.3; = p.S95L on NM_000612.6) | Missense Mutation (SNP) | VAF 88/400 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1457247306, COSV100324315; called by muse, mutect2, varscan2
- IL12RB1 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100443073; called by muse, mutect2, varscan2
- IL1RAP | c.864del p.K288Nfs*15 | Frame Shift Del (DEL) | VAF 28/142 reads (20%) | catalogued as rs780458834, COSV50762431; called by pindel, varscan2
- IL4R | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as rs115310233; called by muse, mutect2, varscan2
- ING3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.982); catalogued as rs768225061; called by muse, mutect2, varscan2
- IP6K3 | c.503G>T p.R168M | Missense Mutation (SNP) | VAF 101/458 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as COSV53388974; called by muse, mutect2, varscan2
- IRS2 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 118/509 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs1450781846; called by muse, mutect2, varscan2
- IRX2 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 140/540 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as rs1452266289, COSV57413198, COSV57413760; called by muse, varscan2
- IRX3 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 124/497 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.648); catalogued as rs1455564185, COSV100315379; called by mutect2, varscan2
- ITGA1 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 107/490 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.085); catalogued as rs901051081; called by muse, mutect2, varscan2
- ITGA2 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 34/190 reads (18%) | catalogued as rs762147632, COSV99670867; called by muse, mutect2
- ITIH1 | c.1452T>A p.D484E | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56251828; called by muse, mutect2, varscan2
- ITPR3 | c.2758G>A p.V920M | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.116); catalogued as rs779072484, COSV65405188; called by muse, mutect2, varscan2
- ITPRIP | c.383del p.G128Afs*48 | Frame Shift Del (DEL) | VAF 114/598 reads (19%) | catalogued as rs751596276; called by mutect2, pindel, varscan2
- JAG2 | c.3389C>T p.P1130L | Missense Mutation (SNP) | VAF 153/572 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs752712856; called by muse, mutect2, varscan2
- JAK1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs1456317552, COSV61089702; called by muse, varscan2
- JAKMIP3 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 100/423 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as rs745792121, COSV53824595; called by muse, mutect2, varscan2
- KALRN | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1486661865, COSV53773122; called by muse, mutect2, varscan2
- KATNA1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as rs1202113077; called by muse, mutect2, varscan2
- KCNA4 | c.1007G>T p.R336M | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV60256257, COSV60256575; called by muse, mutect2, varscan2
- KCNG1 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV65367972; called by muse, mutect2, varscan2
- KCNG2 | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 95/553 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60269312; called by muse, mutect2, varscan2
- KCNIP3 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs1322328940, COSV54670210; called by muse, varscan2
- KCNN1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 130/674 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as COSV55838443; called by muse, mutect2, varscan2
- KCNQ3 | c.2078del p.P693Rfs*10 | Frame Shift Del (DEL) | VAF 44/454 reads (10%) | catalogued as COSV66471146; called by mutect2, pindel, varscan2
- KCNQ3 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 64/418 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs1480684032, COSV66472364; called by muse, mutect2, varscan2
- KCTD3 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as COSV99379753; called by muse, mutect2, varscan2
- KDF1 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 80/359 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.823); catalogued as rs1222040567, COSV100264396; called by muse, varscan2
- KDM6A | c.564G>T p.K188N | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65038103; called by muse, mutect2, varscan2
- KHNYN | c.338C>A p.P113H | Missense Mutation (SNP) | VAF 20/443 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV52159673; called by muse, mutect2
- KIAA0319L | c.2120C>T p.T707M | Missense Mutation (SNP) | VAF 47/278 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs764655401, COSV57844637; called by muse, mutect2, varscan2
- KIF23 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99532268; called by muse, mutect2, varscan2
- KMT2D | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs778237222; called by muse, mutect2, varscan2
- KNDC1 | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 140/656 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs768194603; called by muse, mutect2, varscan2
- KNDC1 | c.4913C>T p.A1638V | Missense Mutation (SNP) | VAF 113/506 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs377737494; called by muse, mutect2, varscan2
- KPNA7 | c.1134+1G>A p.X378_splice | Splice Site (SNP) | VAF 49/267 reads (18%) | catalogued as rs953759927; called by muse, mutect2, varscan2
- KRBOX1 | c.165G>A p.V55= | Splice Region (SNP) | VAF 34/176 reads (19%) | catalogued as rs1160276883; called by muse, varscan2
- KRR1 | c.1142del p.K381Sfs*8 | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | catalogued as rs761148574; called by mutect2, varscan2
- KTI12 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 23/525 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs1359898672; called by muse, mutect2
- L3HYPDH | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.109); catalogued as rs1361708079; called by muse, mutect2, varscan2
- LACTBL1 | c.1120G>A p.G374S (on ENST00000618559; = p.G419S on NM_001289974.2) | Missense Mutation (SNP) | VAF 70/533 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1442245635; called by muse, mutect2, varscan2
- LAMA1 | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 69/368 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.284); catalogued as rs765489991; called by muse, mutect2, varscan2
- LAMB4 | c.26del p.L9Cfs*43 | Frame Shift Del (DEL) | VAF 34/163 reads (21%) | catalogued as rs747409331; called by mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 30/178 reads (17%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCMT1 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101111605; called by muse, mutect2, varscan2
- LEFTY1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 71/577 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs370122681, COSV55284132; called by muse, mutect2, varscan2
- LGSN | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs139295115; called by muse, mutect2, varscan2
- LIG1 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 69/489 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs368406296; called by muse, mutect2, varscan2
- LIG1 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746273257, COSV54396452; called by muse, mutect2, varscan2
- LIPC | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 69/413 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs369706830; called by muse, mutect2, varscan2
- LLGL2 | c.3025G>A p.A1009T (on ENST00000392550 / NM_001031803.2; = p.P994= on NM_004524.3) | Missense Mutation (SNP) | VAF 57/568 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs61751715; called by muse, mutect2, varscan2
- LMTK3 | c.2175del p.A726Pfs*132 | Frame Shift Del (DEL) | VAF 86/270 reads (32%) | catalogued as rs1555901301; called by mutect2, varscan2
- LPIN1 | c.2461G>A p.V821I | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as rs557485971, COSV56764633; called by muse, varscan2
- LRFN1 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 145/685 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1448272152; called by muse, mutect2, varscan2
- LRP2BP | c.771A>T p.K257N | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1476198441; called by muse, mutect2, varscan2
- LRP3 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 166/708 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs768597836; called by muse, mutect2, varscan2
- LRP5 | c.4354G>A p.A1452T | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs780134568, COSV53719552; called by muse, mutect2
- LRP6 | c.4377dup p.Y1460Lfs*2 | Frame Shift Ins (INS) | VAF 36/330 reads (11%) | catalogued as rs764620253; called by mutect2, pindel
- LRRC38 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 135/581 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV101065861; called by muse, mutect2, varscan2
- LRRC63 | c.76dup p.T26Nfs*5 | Frame Shift Ins (INS) | VAF 19/148 reads (13%) | catalogued as rs1319697316; called by mutect2, varscan2
- LRRK2 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368291361; called by muse, mutect2, varscan2
- LSS | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 87/441 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs142026899; called by muse, mutect2, varscan2
- LTBP2 | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1466624298, COSV56207435; called by muse, mutect2, varscan2
- LTBP2 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 76/420 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1221770546; ClinVar: not provided; called by muse, mutect2, varscan2
- LZTS1 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 86/434 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs146827533; called by muse, mutect2, varscan2
- MACC1 | c.1232del p.N411Tfs*23 | Frame Shift Del (DEL) | VAF 42/229 reads (18%) | catalogued as rs761473889, COSV60540689; called by mutect2, varscan2
- MACF1 | c.1217del p.G406Efs*5 | Frame Shift Del (DEL) | VAF 47/298 reads (16%) | catalogued as rs1557563336; called by mutect2, pindel, varscan2
- MAGEA8 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99674324; called by muse, mutect2
- MAGEC3 | c.1774C>A p.L592I | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.127); catalogued as COSV68923870; called by muse, mutect2, varscan2
- MAGIX | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 176/611 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557097535, COSV66255897; called by muse, mutect2, varscan2
- MAP3K15 | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 95/355 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58839973; called by muse, mutect2, varscan2
- MAP7D3 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV60171013; called by muse, mutect2, varscan2
- MAST4 | c.5068C>T p.R1690* (on ENST00000403625 / NM_001164664.2; = p.R1501* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 91/401 reads (23%) | catalogued as rs909691151, COSV99844046; called by muse, mutect2, varscan2
- MC3R | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 57/438 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs961130091, COSV54763087; called by muse, mutect2, varscan2
- MCM3AP | c.2920G>A p.V974I | Missense Mutation (SNP) | VAF 77/382 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs758257201, COSV52440904; called by muse, mutect2, varscan2
- MCPH1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780973934, COSV60913544; called by muse, mutect2, varscan2
- MED15 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 70/321 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.271); catalogued as rs776469364, COSV99488133; called by muse, mutect2, varscan2
- MEI1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 75/584 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV55903743; called by muse, mutect2, varscan2
- MFAP2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373562256; called by muse, mutect2, varscan2
- MIDN | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 81/424 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1488829360, COSV56296213; called by muse, mutect2, varscan2
- MSL1 | c.970C>T p.R324W (on ENST00000398532 / NM_001365919.1; = p.R61W on NM_001012241.2) | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs755174122; called by muse, mutect2, varscan2
- MSR1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs370472553, COSV100027792; called by muse, mutect2, varscan2
- MTSS2 | c.2209G>A p.V737I | Missense Mutation (SNP) | VAF 114/493 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs780793409; called by muse, mutect2, varscan2
- MUC12 | c.3325G>A p.V1109I (on ENST00000379442; = p.V966I on NM_001164462.1) | Missense Mutation (SNP) | VAF 103/429 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.101); catalogued as rs1419974050; called by muse, mutect2, varscan2
- MUC12 | c.16147G>A p.V5383M (on ENST00000379442; = p.V5240M on NM_001164462.1) | Missense Mutation (SNP) | VAF 95/510 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs750066727; called by muse, mutect2, varscan2
- MUC16 | c.30940del p.D10314Mfs*38 | Frame Shift Del (DEL) | VAF 68/284 reads (24%) | catalogued as COSV101201474; called by mutect2, pindel, varscan2
- MUC4 | c.13888C>T p.R4630C (on ENST00000463781 / NM_018406.7; = p.R394C on NM_004532.6) | Missense Mutation (SNP) | VAF 100/452 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.828); catalogued as rs750211557, COSV57774542; called by muse, mutect2, varscan2
- MUC4 | c.5335G>A p.V1779I | Missense Mutation (SNP) | VAF 78/483 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.101); catalogued as rs1297107126; called by muse, mutect2, varscan2
- MUC5B | c.11938G>A p.A3980T | Missense Mutation (SNP) | VAF 77/490 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs778338583; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 154/603 reads (26%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYADM | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 58/493 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs772229229, COSV61240621; called by muse, mutect2, varscan2
- MYBL1 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as rs757999984; called by muse, mutect2, varscan2
- MYBPC2 | c.2926del p.T976Pfs*76 | Frame Shift Del (DEL) | VAF 34/250 reads (14%) | catalogued as rs757263482; called by mutect2, pindel, varscan2
- MYEF2 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as rs1331806615; called by muse, mutect2, varscan2
- MYF6 | c.37T>G p.F13V | Missense Mutation (SNP) | VAF 64/286 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57353064; called by muse, mutect2, varscan2
- MYH4 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs201896271; called by muse, mutect2, varscan2
- MYO10 | c.1874C>T p.T625M | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as rs1334046909; called by muse, varscan2
- MYO15A | c.5053G>A p.A1685T | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs780793940, COSV52752859; called by muse, mutect2, varscan2
- MYO16 | c.2607dup p.L870Tfs*45 | Frame Shift Ins (INS) | VAF 40/192 reads (21%) | catalogued as rs1566464398; called by mutect2, varscan2
- MYO5B | c.3452A>C p.K1151T | Missense Mutation (SNP) | VAF 19/412 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV53233301; called by muse, mutect2
- NAGA | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 50/436 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140775168; called by muse, mutect2, varscan2
- NAV3 | c.3679G>A p.A1227T | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as rs775200279, COSV57073657; called by muse, mutect2, varscan2
- NAV3 | c.5740C>A p.R1914S (on ENST00000397909 / NM_001024383.2; = p.R1892S on NM_014903.6) | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99893403; called by muse, mutect2, varscan2
- NBEAL2 | c.1059del p.E354Rfs*11 | Frame Shift Del (DEL) | VAF 86/530 reads (16%) | catalogued as rs1559590473; called by mutect2, pindel, varscan2
- NEFL | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 88/547 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.832); catalogued as rs1563251843, COSV55338447; called by muse, varscan2
- NEK1 | c.2556del p.V853Yfs*8 | Frame Shift Del (DEL) | VAF 42/152 reads (28%) | catalogued as rs760894879; called by mutect2, varscan2
- NEK2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779581769; called by muse, mutect2, varscan2
- NELFCD | c.791del p.G264Afs*27 (on ENST00000602795; = p.G246Afs*27 on NM_198976.4) | Frame Shift Del (DEL) | VAF 96/547 reads (18%) | catalogued as rs920632659; called by mutect2, pindel, varscan2
- NEUROG2 | c.42G>T p.E14D | Missense Mutation (SNP) | VAF 61/318 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.079); catalogued as COSV100511920; called by muse, varscan2
- NFASC | c.265C>T p.R89W (on ENST00000339876 / NM_001378329.1; = p.R83W on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/358 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs922818448, COSV100362566, COSV58380022; called by muse, mutect2, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 42/182 reads (23%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NHSL1 | c.2399C>T p.P800L | Missense Mutation (SNP) | VAF 98/563 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as rs1052760043; called by muse, mutect2, varscan2
- NHSL2 | c.745C>T p.P249S (on ENST00000510661; = p.P615S on NM_001013627.2) | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1569484083, COSV101030001; called by muse, mutect2, varscan2
- NIBAN3 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 114/466 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs758986033, COSV56309137; called by muse, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 36/289 reads (12%) | catalogued as rs763440516; called by mutect2, varscan2
- NLGN3 | c.2149T>A p.S717T (on ENST00000358741 / NM_181303.2; = p.S697T on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/514 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100704560; called by muse, mutect2, varscan2
- NOL4L | c.396dup p.Y133Lfs*18 | Frame Shift Ins (INS) | VAF 45/203 reads (22%) | catalogued as rs751187638; called by mutect2, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 59/320 reads (18%) | catalogued as rs765756993; called by mutect2, varscan2
- NOX4 | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1266989906; called by muse, mutect2, varscan2
- NPHP4 | c.3506dup p.V1170Sfs*13 | Frame Shift Ins (INS) | VAF 74/366 reads (20%) | catalogued as rs775221217; called by mutect2, pindel, varscan2
- NPHP4 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 71/387 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs1277122651; called by muse, mutect2, varscan2
- NPHP4 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 75/407 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1409073589; called by muse, mutect2, varscan2
- NPIPB5 | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 132/1931 reads (7%) | SIFT tolerated, low confidence (0.06); catalogued as rs574902725; called by muse, mutect2
- NR0B1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 146/696 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs757381652, COSV66765045; called by muse, mutect2, varscan2
- NR1H3 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 110/447 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs773695020; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 51/260 reads (20%) | catalogued as rs774343392; called by mutect2, varscan2
- NR2C2AP | c.84del p.K28Nfs*22 | Frame Shift Del (DEL) | VAF 54/265 reads (20%) | catalogued as rs780246694; called by mutect2, pindel, varscan2
- NR2E3 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779903522, CM1010250; called by muse, mutect2, varscan2
- NRDE2 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 84/353 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371403922, COSV62963424; called by muse, mutect2, varscan2
- NRG3 | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 108/460 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.154); catalogued as rs748169278; called by muse, mutect2, varscan2
- NUP210 | c.403del p.L135Wfs*3 | Frame Shift Del (DEL) | VAF 55/329 reads (17%) | catalogued as rs762804106; called by mutect2, pindel, varscan2
- NYAP2 | c.1562G>A p.G521D | Missense Mutation (SNP) | VAF 117/454 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56016792; called by muse, mutect2, varscan2
- OBSCN | c.21110C>A p.P7037H | Missense Mutation (SNP) | VAF 157/678 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV63633299; called by muse, mutect2, varscan2
- OPA1 | c.2087C>T p.A696V (on ENST00000361510 / NM_130837.3; = p.A641V on NM_015560.3) | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1315893899; called by muse, mutect2, varscan2
- OPLAH | c.2180G>A p.G727D | Missense Mutation (SNP) | VAF 93/590 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV101470810; called by muse, mutect2, varscan2
- OPN5 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1008543429, COSV55244102; called by muse, varscan2
- OR10G9 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 64/433 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763187156, COSV66686209; called by muse, varscan2
- OR13C2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs768722886; called by muse, mutect2, varscan2
- OR2J3 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs372756606; called by muse, mutect2, varscan2
- OR4A16 | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV59044071; called by muse, mutect2, varscan2
- OR51F2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs267602910, COSV59065576; called by muse, mutect2, varscan2
- OR52K2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 77/358 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs750840213, COSV57835623; called by muse, mutect2, varscan2
- OR5G3 | c.175A>G p.M59V | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs987782942; called by muse, mutect2, varscan2
- OSBP2 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548187834, COSV60239437; called by muse, mutect2, varscan2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 73/352 reads (21%) | catalogued as rs780916980; called by mutect2, varscan2
- OTUD7B | c.2304del p.Y769Tfs*59 | Frame Shift Del (DEL) | VAF 82/342 reads (24%) | catalogued as COSV64917254; called by mutect2, varscan2
- PADI2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs765913066, COSV64946804; called by muse, varscan2
- PALB2 | c.886del p.M296* | Frame Shift Del (DEL) | VAF 40/210 reads (19%) | catalogued as CD147527; called by mutect2, varscan2
- PANK3 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs372745752; called by muse, mutect2, varscan2
- PANK4 | c.72dup p.D25Rfs*50 | Frame Shift Ins (INS) | VAF 83/371 reads (22%) | catalogued as rs768596064; called by mutect2, pindel, varscan2
- PAX6 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749244084, CM992382, COSV53793239; called by muse, mutect2, varscan2
- PCDH11X | c.2251G>T p.V751F | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53468886; called by muse, mutect2, varscan2
- PCDH12 | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 82/430 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs753657439; called by muse, mutect2, varscan2
- PCDH17 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 105/432 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.24); catalogued as COSV64971497; called by muse, mutect2, varscan2
- PCDH19 | c.1958_1959dup p.A654Lfs*7 | Frame Shift Ins (INS) | VAF 78/412 reads (19%) | catalogued as rs796052835; called by mutect2, varscan2
- PCDH7 | c.626del p.G209Afs*52 | Frame Shift Del (DEL) | VAF 48/320 reads (15%) | catalogued as rs1464808028; called by mutect2, pindel, varscan2
- PCDH8 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 70/617 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs924126246, COSV58814778; called by muse, mutect2, varscan2
- PCDHA8 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 189/812 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as COSV65337680, COSV65339512; called by muse, mutect2, varscan2
- PCDHB10 | c.1459A>G p.T487A | Missense Mutation (SNP) | VAF 70/490 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as rs1554284244; called by muse, mutect2, varscan2
- PCDHGA1 | c.351dup p.P118Sfs*3 | Frame Shift Ins (INS) | VAF 34/199 reads (17%) | catalogued as rs1278168513; called by mutect2, pindel, varscan2
- PCNX1 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.707); catalogued as rs768563638, COSV53093464; called by muse, varscan2
- PDE6B | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 88/439 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750845388; called by muse, varscan2
- PDGFRA | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs999173790; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGAP6 | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 113/561 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs1459397104, COSV99170877; called by muse, mutect2, varscan2
- PIGM | c.346_348dup p.L116dup | In Frame Ins (INS) | VAF 73/336 reads (22%) | catalogued as COSV63635574; called by mutect2, varscan2
- PIGT | c.1730del p.P577Hfs*67 | Frame Shift Del (DEL) | VAF 55/341 reads (16%) | catalogued as rs760395465; called by mutect2, pindel, varscan2
- PIK3CD | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.13); catalogued as rs1214315014, COSV63129733; called by muse, varscan2
- PIP5K1C | c.1979dup p.A661Gfs*81 | Frame Shift Ins (INS) | VAF 86/424 reads (20%) | catalogued as rs748532409; called by mutect2, varscan2
- PITPNM1 | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 135/479 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs763109640; called by muse, mutect2, varscan2
- PITX2 | c.434G>A p.R145H (on ENST00000354925 / NM_001204397.1; = p.R152H on NM_000325.6) | Missense Mutation (SNP) | VAF 66/356 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60742016; called by muse, mutect2, varscan2
- PKD1L1 | c.6679C>T p.R2227C | Missense Mutation (SNP) | VAF 140/361 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1193252581, COSV56958099; called by muse, mutect2, varscan2
- PKHD1L1 | c.3958G>A p.D1320N | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV101006335; called by muse, mutect2, varscan2
- PKLR | c.644dup p.R216Pfs*5 | Frame Shift Ins (INS) | VAF 124/622 reads (20%) | catalogued as rs1557959906; called by mutect2, pindel, varscan2
- PLA1A | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as rs1323469402; called by muse, varscan2
- PLXNA3 | c.2244G>T p.S748= | Splice Region (SNP) | VAF 27/681 reads (4%) | catalogued as rs782255076; called by muse, mutect2
- PLXNA4 | c.2956G>T p.V986L | Missense Mutation (SNP) | VAF 83/473 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs918009709; called by muse, mutect2, varscan2
- PMS2 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 44/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs587780055, COSV99764357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 88/484 reads (18%) | catalogued as rs761459630; called by mutect2, pindel, varscan2
- POLG | c.2986C>T p.R996W | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs202229893; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POMC | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 125/559 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); catalogued as rs1199953669; called by muse, mutect2, varscan2
- PON2 | c.195dup p.S66* | Frame Shift Ins (INS) | VAF 24/196 reads (12%) | catalogued as rs1201102139; called by mutect2, varscan2
- POTEI | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 99/596 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.811); catalogued as rs28450341, COSV71576069; called by muse, mutect2, varscan2
- PPFIA2 | c.3104C>A p.P1035H | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100333670; called by muse, mutect2, varscan2
- PPP4R1 | c.203G>A p.R68Q (on ENST00000400556 / NM_001042388.3; = p.R51Q on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs762871985; called by muse, mutect2, varscan2
- PPP6R1 | c.2328del p.S777Qfs*141 | Frame Shift Del (DEL) | VAF 64/531 reads (12%) | catalogued as COSV58983731; called by mutect2, pindel, varscan2
- PRDM14 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 50/411 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs772538982; called by muse, mutect2, varscan2
- PRDM15 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 98/434 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs371587258, COSV54160566; called by muse, mutect2, varscan2
- PRDM5 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1346294925, COSV53358261; called by muse, mutect2, varscan2
- PRICKLE3 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 76/448 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1557100647; called by muse, mutect2, varscan2
- PRKDC | c.2737C>T p.R913* | Nonsense Mutation (SNP) | VAF 54/338 reads (16%) | catalogued as COSV58059167; called by muse, mutect2, varscan2
- PRPF31 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 127/609 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745566366, CD153015, COSV58085306; called by muse, mutect2, varscan2
- PRR16 | c.830del p.P277Lfs*20 (on ENST00000407149 / NM_001300783.2; = p.P254Lfs*20 on NM_016644.2) | Frame Shift Del (DEL) | VAF 53/286 reads (19%) | catalogued as COSV65401020; called by mutect2, varscan2
- PRR23C | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 129/510 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV68827429; called by muse, mutect2, varscan2
- PRR36 | c.191del p.G64Afs*146 | Frame Shift Del (DEL) | VAF 76/661 reads (11%) | catalogued as rs1327235205; called by mutect2, pindel, varscan2
- PRRC2A | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 84/422 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1179360965; called by muse, mutect2, varscan2
- PRRT1B | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 112/536 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs897992178; called by muse, varscan2
- PRSS12 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 56/306 reads (18%) | catalogued as rs377444158, COSV56608219; called by muse, mutect2, varscan2
- PRSS53 | c.108dup p.K37Qfs*44 | Frame Shift Ins (INS) | VAF 110/470 reads (23%) | catalogued as rs759089621; called by mutect2, varscan2
- PRSS55 | c.756del p.P253Lfs*18 | Frame Shift Del (DEL) | VAF 45/270 reads (17%) | catalogued as rs751829343; called by mutect2, pindel, varscan2
- PRSS56 | c.499del p.E167Sfs*8 | Frame Shift Del (DEL) | VAF 105/484 reads (22%) | catalogued as COSV51326933; called by mutect2, pindel, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PRX | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 129/573 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.356); catalogued as rs745593860, COSV52529287; called by muse, mutect2, varscan2
- PSD | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 138/620 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs149849990; called by muse, mutect2, varscan2
- PSD | c.593del p.G198Afs*19 | Frame Shift Del (DEL) | VAF 117/511 reads (23%) | catalogued as COSV99194092; called by mutect2, varscan2
- PSMC4 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV50096682; called by muse, mutect2, varscan2
- PTPN14 | c.1707del p.Y570Tfs*29 | Frame Shift Del (DEL) | VAF 99/529 reads (19%) | catalogued as COSV65287671; called by mutect2, pindel, varscan2
- PTPN3 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs776311554, COSV52709280; called by muse, mutect2, varscan2
- PTPN3 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs777977887, COSV52702848; called by muse, mutect2
- PTPRB | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760734939, COSV54238560; called by muse, mutect2, varscan2
- PTPRG | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs148761591; called by muse, mutect2, varscan2
- PTPRQ | c.2497del p.Q833Kfs*18 (on ENST00000616559; = p.Q791Kfs*18 on NM_001145026.2) | Frame Shift Del (DEL) | VAF 28/139 reads (20%) | catalogued as rs935928481, COSV57034264; called by mutect2, pindel, varscan2
- PTTG1 | c.275del p.K92Rfs*2 | Frame Shift Del (DEL) | VAF 30/155 reads (19%) | catalogued as rs776127942; called by mutect2, pindel, varscan2
- PUM1 | c.2165G>T p.S722I | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV57084426; called by muse, mutect2
- PWP1 | c.1041_1042del p.R347Sfs*17 | Frame Shift Del (DEL) | VAF 50/300 reads (17%) | catalogued as rs765444638; called by pindel, varscan2
- PYROXD2 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 79/321 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs776206354; called by muse, mutect2, varscan2
- QDPR | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 84/336 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1210367, CM920601, COSV55549744; called by muse, mutect2, varscan2
- QRICH2 | c.3226A>G p.I1076V | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1374046738; called by muse, mutect2, varscan2
- R3HCC1 | c.1322G>A p.R441H (on ENST00000411463; = p.R401H on NM_001136108.3) | Missense Mutation (SNP) | VAF 72/446 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs772503867, COSV56120207; called by muse, mutect2, varscan2
- RAPGEF2 | c.3574C>T p.R1192W | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as rs756374875, COSV52427350; called by muse, mutect2, varscan2
- RASSF1 | c.731G>A p.R244H (on ENST00000357043 / NM_170714.2; = p.R240H on NM_007182.5) | Missense Mutation (SNP) | VAF 88/416 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs751246285, COSV51701475; called by muse, mutect2, varscan2
- RBM48 | c.533G>C p.G178A | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs1344099871; called by muse, mutect2, varscan2
- RBM6 | c.2288G>A p.R763Q | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.12); catalogued as rs201064128; called by muse, mutect2, varscan2
- RBP3 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 16/559 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs140357670; called by muse, mutect2
- RCBTB2 | c.298dup p.I100Nfs*27 | Frame Shift Ins (INS) | VAF 41/204 reads (20%) | catalogued as rs767856805; called by mutect2, varscan2
- RELN | c.5976A>T p.E1992D | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.708); catalogued as COSV58996577; called by muse, mutect2, varscan2
- RELN | c.3563C>T p.A1188V | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.259); catalogued as rs776929077; called by muse, varscan2
- RFX7 | c.1043G>A p.R348H (on ENST00000559447 / NM_001368074.1; = p.R445H on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/290 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs760538628; called by muse, mutect2, varscan2
- RGMA | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 31/538 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1476605596; called by muse, mutect2
- RHBDF1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 87/428 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1316734030, COSV99244715; called by muse, mutect2, varscan2
- RICTOR | c.3404C>T p.T1135M | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371456052, COSV57119597; called by muse, mutect2, varscan2
- RIN1 | c.682del p.L228Cfs*6 | Frame Shift Del (DEL) | VAF 128/601 reads (21%) | catalogued as rs1262784452; called by mutect2, pindel, varscan2
- RIOX1 | c.150G>A p.M50I | Missense Mutation (SNP) | VAF 125/499 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1479345852; called by muse, mutect2, varscan2
- RIT2 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99951437; called by muse, varscan2
- RLN1 | c.479del p.K160Rfs*14 | Frame Shift Del (DEL) | VAF 42/253 reads (17%) | catalogued as rs758351039; called by mutect2, pindel, varscan2
- RNF213 | c.7718C>T p.P2573L | Missense Mutation (SNP) | VAF 52/350 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771921862; called by muse, mutect2, varscan2
- RNF31 | c.1759G>T p.G587C | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53761595; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 202/621 reads (33%) | catalogued as rs755128667, COSV68457540; called by pindel, varscan2
- ROS1 | c.5743G>A p.G1915R | Missense Mutation (SNP) | VAF 179/409 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.383); catalogued as rs759091073, COSV63861219; called by muse, mutect2, varscan2
- RPS6KA6 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758041363, COSV53117486; called by muse, mutect2, varscan2
- RRBP1 | c.2149G>A p.A717T (on ENST00000377813 / NM_001365613.2; = p.A284T on NM_004587.3) | Missense Mutation (SNP) | VAF 66/321 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.3); catalogued as rs1277750035, COSV99854548; called by muse, mutect2, varscan2
- RSPH10B | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 41/557 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.156); catalogued as rs754891560; called by muse, mutect2
- RTL1 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 81/379 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs770333384, COSV66017265; called by muse, mutect2, varscan2
- RUSC1 | c.2647C>T p.R883C (on ENST00000368352 / NM_001105203.2; = p.R414C on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/435 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs376381554; called by muse, mutect2, varscan2
- RYR1 | c.7697C>T p.A2566V | Missense Mutation (SNP) | VAF 126/503 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs1285547623, COSV62089550; called by muse, varscan2
- RYR1 | c.10052C>T p.P3351L | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs970909296, COSV62110543; called by muse, mutect2
- SAMD4A | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 105/504 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs1351693123; called by muse, mutect2, varscan2
- SAMD9 | c.3813del p.F1271Lfs*8 | Frame Shift Del (DEL) | VAF 27/174 reads (16%) | catalogued as rs748414027; called by mutect2, pindel, varscan2
- SBF1 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 73/344 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as rs1046180703; called by muse, mutect2, varscan2
- SCAI | c.419G>A p.R140H (on ENST00000336505 / NM_001144877.3; = p.R163H on NM_173690.5) | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1359615510, COSV100332843; called by muse, mutect2
- SCN8A | c.3361G>T p.G1121C | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV100634246; called by muse, mutect2, varscan2
- SCTR | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 89/394 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99191740; called by muse, mutect2, varscan2
- SEC24A | c.1927A>G p.T643A | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1337497101; called by muse, mutect2, varscan2
- SELE | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 72/329 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs139137736; called by muse, mutect2, varscan2
- SEM1 | c.293dup p.P99Tfs*7 | Frame Shift Ins (INS) | VAF 79/327 reads (24%) | catalogued as rs1256833740; called by mutect2, pindel, varscan2
- SEMA5B | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 100/447 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs909887013; called by muse, mutect2, varscan2
- SEZ6L | c.1876G>T p.A626S | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV50658141, COSV99963307; called by muse, mutect2, varscan2
- SFXN5 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs372326606; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 28/116 reads (24%) | catalogued as rs1260834379; called by mutect2, varscan2
- SH2D3C | c.2184C>A p.S728R (on ENST00000314830 / NM_170600.3; = p.S571R on NM_005489.4) | Missense Mutation (SNP) | VAF 66/354 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.954); catalogued as rs774965690; called by muse, mutect2
- SHANK1 | c.3436G>A p.A1146T | Missense Mutation (SNP) | VAF 141/668 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs777507884, COSV53256235, COSV53257538; called by muse, mutect2, varscan2
- SHANK3 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1215434429; called by muse, varscan2
- SHKBP1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as rs1203695526, COSV52540731; called by muse, mutect2, varscan2
- SIGLEC9 | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 82/387 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV51585886, COSV51586394; called by muse, mutect2, varscan2
- SIM1 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53494232, COSV99491940; called by muse, mutect2, varscan2
- SLC10A4 | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 57/283 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56719389; called by muse, mutect2, varscan2
- SLC15A3 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 139/619 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs554958129, COSV99928881; called by muse, mutect2, varscan2
- SLC19A1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 95/433 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.387); catalogued as rs772342183, COSV60752832; called by muse, mutect2, varscan2
- SLC22A2 | c.1577T>C p.I526T | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.785); catalogued as rs368218693; called by muse, mutect2, varscan2
- SLC25A25 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 96/513 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.692); catalogued as rs1222697568, COSV66087084; called by muse, varscan2
- SLC35B3 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1171854322, COSV100217320; called by muse, mutect2, varscan2
- SLC36A1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs201241765, COSV54652094; called by muse, mutect2, varscan2
- SLC38A10 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 78/322 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.807); catalogued as rs754971031; called by muse, mutect2, varscan2
- SLC45A4 | c.1973G>A p.R658Q (on ENST00000517878 / NM_001286646.2; = p.R607Q on NM_001080431.2) | Missense Mutation (SNP) | VAF 74/424 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1487480761; called by muse, mutect2, varscan2
- SLC8B1 | c.423C>T p.G141= | Splice Region (SNP) | VAF 32/242 reads (13%) | catalogued as rs1566238954, COSV99176671; called by muse, varscan2
- SMCHD1 | c.2040del p.K680Nfs*3 | Frame Shift Del (DEL) | VAF 22/153 reads (14%) | catalogued as rs766211852; called by mutect2, pindel, varscan2
- SORCS2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 98/451 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as rs769656488; called by muse, mutect2, varscan2
- SORCS2 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 65/343 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs763613488; called by muse, mutect2, varscan2
- SOST | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 134/544 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs1201235150; called by muse, mutect2, varscan2
- SOX11 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 111/559 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as rs1276263281; called by muse, mutect2, varscan2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 50/176 reads (28%) | catalogued as rs371303534; called by mutect2, varscan2
- SPATS2L | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62350519; called by muse, mutect2, varscan2
- SPICE1 | c.1808_1809del p.R603Mfs*20 | Frame Shift Del (DEL) | VAF 28/220 reads (13%) | catalogued as rs1481608687; called by pindel, varscan2
- SPINK7 | c.87del p.V30Wfs*42 | Frame Shift Del (DEL) | VAF 33/119 reads (28%) | catalogued as rs747884448; called by mutect2, pindel, varscan2
- SPINK9 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as rs1229993032; called by muse, mutect2
- SPRTN | c.1263dup p.I422Yfs*11 | Frame Shift Ins (INS) | VAF 28/156 reads (18%) | catalogued as rs567805129; called by mutect2, varscan2
- SRP72 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs767820780, COSV100714332; called by muse, varscan2
- STAG3 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs145719011; called by muse, varscan2
- STARD8 | c.2618del p.P873Qfs*28 | Frame Shift Del (DEL) | VAF 96/512 reads (19%) | catalogued as rs761897392; called by mutect2, varscan2
- STEAP4 | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV57330403; called by muse, mutect2, varscan2
- STK11IP | c.2785del p.Q929Sfs*39 | Frame Shift Del (DEL) | VAF 74/316 reads (23%) | catalogued as rs1559188516; called by mutect2, varscan2
- STOX1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs770130603, COSV53813330; called by muse, mutect2, varscan2
- SUGCT | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.523); catalogued as rs201433905; called by muse, mutect2, varscan2
- SUGP2 | c.2047C>T p.L683F | Missense Mutation (SNP) | VAF 112/528 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100432346; called by muse, mutect2, varscan2
- TBC1D10C | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 168/571 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs531173208; called by muse, mutect2, varscan2
- TBC1D10C | c.1281dup p.I428Hfs*26 | Frame Shift Ins (INS) | VAF 82/366 reads (22%) | catalogued as rs756043635; called by mutect2, varscan2
- TBC1D25 | c.1347del p.S450Afs*22 | Frame Shift Del (DEL) | VAF 50/536 reads (9%) | catalogued as rs1556985760; called by pindel, varscan2
- TBKBP1 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 78/388 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs202103128; called by muse, mutect2, varscan2
- TBPL1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs201622346, COSV51599744; called by muse, mutect2, varscan2
- TBRG4 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 75/403 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs754159048; called by muse, mutect2, varscan2
- TECTA | c.4858G>A p.G1620S | Missense Mutation (SNP) | VAF 92/366 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs142929996; called by muse, mutect2, varscan2
- TFAP2B | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53825738; called by muse, mutect2
- TFB2M | c.795+1G>A p.X265_splice | Splice Site (SNP) | VAF 36/154 reads (23%) | catalogued as rs750796159, COSV100830441; called by muse, mutect2, varscan2
- TFPI2 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 74/464 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs751463825, COSV55989782; called by muse, mutect2, varscan2
- TIMM17B | c.212dup p.L72Pfs*56 | Frame Shift Ins (INS) | VAF 73/359 reads (20%) | catalogued as rs782500597; called by mutect2, varscan2
- TJP3 | c.1549G>C p.A517P | Missense Mutation (SNP) | VAF 115/479 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.416); catalogued as rs777561955, COSV53664549; called by muse, mutect2, varscan2
- TLR1 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as rs1397983528; called by muse, mutect2, varscan2
- TMEM130 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 32/819 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs781824607, COSV59557727; called by muse, mutect2
- TMEM140 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 125/673 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150916088; called by muse, mutect2, varscan2
- TMEM255B | c.969del p.Y324Tfs*9 | Frame Shift Del (DEL) | VAF 70/422 reads (17%) | catalogued as COSV100944145; called by pindel, varscan2
- TMSB15A | c.80del p.N27Ifs*49 | Frame Shift Del (DEL) | VAF 34/180 reads (19%) | catalogued as rs782090690; called by mutect2, pindel, varscan2
- TNFAIP3 | c.2274dup p.K759Qfs*10 | Frame Shift Ins (INS) | VAF 74/408 reads (18%) | catalogued as rs775280214; called by mutect2, varscan2
- TNPO3 | c.428dup p.L143Ffs*10 | Frame Shift Ins (INS) | VAF 22/236 reads (9%) | catalogued as rs1317864999; called by mutect2, pindel
- TNRC18 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 123/722 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1317710865, COSV101259491; called by muse, mutect2, varscan2
- TNS3 | c.3355A>G p.S1119G | Missense Mutation (SNP) | VAF 109/601 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.877); catalogued as rs1263422191; called by muse, mutect2, varscan2
- TNXB | c.11388G>T p.E3796D (on ENST00000647633; = p.E3549D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/526 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV100926154; called by muse, mutect2
- TOE1 | c.51C>T p.D17= | Splice Region (SNP) | VAF 70/301 reads (23%) | catalogued as rs774689873; called by muse, mutect2, varscan2
- TOLLIP | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 30/437 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1334445574; called by muse, mutect2
- TP53 | c.1146del p.K382Nfs*40 | Frame Shift Del (DEL) | VAF 46/240 reads (19%) | catalogued as CD126191; called by mutect2, pindel, varscan2
- TP73 | c.1172A>G p.Q391R | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.246); catalogued as rs530995550, COSV60698163; called by muse, mutect2, varscan2
- TPBGL | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs537559298; called by muse, mutect2, varscan2
- TPCN1 | c.791G>A p.S264N | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as rs557584323; called by muse, varscan2
- TPM1 | c.421del p.M141Wfs*8 | Frame Shift Del (DEL) | VAF 12/142 reads (8%) | catalogued as CM1410916; called by mutect2, pindel
- TPTE2 | c.529C>T p.R177* (on ENST00000400230 / NM_199254.2; = p.R100* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 17/104 reads (16%) | catalogued as rs538397448, COSV55016766, COSV55028827; called by muse, mutect2, varscan2
- TRBJ2-3 | c.5C>T p.T2I | Missense Mutation (SNP) | VAF 97/489 reads (20%) | PolyPhen benign (0.354); catalogued as rs1554511542; called by muse, mutect2, varscan2
- TRDV2 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs374840657; called by muse, mutect2, varscan2
- TRGV3 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as rs1165833816; called by muse, mutect2, varscan2
- TRIM31 | c.950T>C p.M317T | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs181406164; called by muse, mutect2, varscan2
- TRIM62 | c.1217G>T p.R406L | Missense Mutation (SNP) | VAF 107/492 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV52222038; called by muse, mutect2, varscan2
- TRMT1 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 67/583 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs144546583; called by muse, mutect2, varscan2
- TRMT61A | c.*4del | Frame Shift Del (DEL) | VAF 78/368 reads (21%) | catalogued as rs1244254158; called by mutect2, pindel, varscan2
- TRPA1 | c.1274del p.G425Afs*5 | Frame Shift Del (DEL) | VAF 28/252 reads (11%) | catalogued as rs759260579; called by mutect2, pindel, varscan2
- TRRAP | c.7826C>T p.A2609V (on ENST00000359863 / NM_001244580.1; = p.A2591V on NM_003496.3) | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as rs201688844; called by muse, mutect2, varscan2
- TSPAN32 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 66/324 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs759043414, COSV51719620; called by muse, mutect2, varscan2
- TSPOAP1 | c.4616C>T p.P1539L | Missense Mutation (SNP) | VAF 125/582 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs140503332; called by muse, mutect2, varscan2
- TTC21A | c.363G>A p.W121* | Nonsense Mutation (SNP) | VAF 62/318 reads (19%) | catalogued as COSV57183327; called by muse, varscan2
- TTC21A | c.377A>G p.H126R | Missense Mutation (SNP) | VAF 78/306 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs774572100; called by muse, varscan2
- TTC23 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 59/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755761200, COSV50440532; called by muse, mutect2, varscan2
- TTC27 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs1448237690; called by muse, mutect2, varscan2
- TTC28 | c.2812G>A p.V938M | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1440314297; called by muse, mutect2, varscan2
- TTF1 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 72/407 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV57502195; called by muse, mutect2, varscan2
- TTI1 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs372481675; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | catalogued as rs768996038, COSV57882295; called by mutect2, pindel, varscan2
- TTN | c.79760G>A p.R26587H (on ENST00000591111; = p.R19163H on NM_003319.4) | Missense Mutation (SNP) | VAF 99/248 reads (40%) | PolyPhen benign (0.015); catalogued as rs768301442; called by muse, mutect2, varscan2
- TTN | c.36466C>T p.P12156S (on ENST00000591111; = p.P4732S on NM_003319.4) | Missense Mutation (SNP) | VAF 66/288 reads (23%) | PolyPhen probably damaging (0.951); catalogued as COSV100631554; called by muse, mutect2, varscan2
- TUBD1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as rs373399411; called by muse, mutect2, varscan2
- TULP4 | c.4480G>A p.A1494T | Missense Mutation (SNP) | VAF 96/365 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs1211158748; called by muse, mutect2, varscan2
- UBA1 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60110939; called by muse, mutect2, varscan2
- UMODL1 | c.453del p.R152Afs*26 | Frame Shift Del (DEL) | VAF 73/404 reads (18%) | catalogued as rs755485498; called by mutect2, pindel, varscan2
- URB1 | c.5422C>T p.R1808C | Missense Mutation (SNP) | VAF 68/357 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs986063421, COSV99060299; called by muse, mutect2, varscan2
- USP20 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 129/626 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201524680, COSV100204898; called by muse, mutect2, varscan2
- USP7 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1383982134; called by muse, mutect2, varscan2
- UTRN | c.4018C>T p.R1340W | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs755991290; called by muse, mutect2, varscan2
- VENTX | c.277del p.R93Vfs*24 | Frame Shift Del (DEL) | VAF 59/375 reads (16%) | catalogued as COSV58085041; called by mutect2, pindel, varscan2
- VIPR1 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV57297557; called by muse, mutect2, varscan2
- VMO1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 81/372 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as rs770762616; called by muse, mutect2, varscan2
- VPS13A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs751155095, COSV62430122; called by muse, mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 37/190 reads (19%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS16 | c.2376C>T p.G792= | Splice Region (SNP) | VAF 50/267 reads (19%) | catalogued as rs751246821, COSV66792900; called by muse, mutect2, varscan2
- VPS26C | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 78/359 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs143165732, COSV99898304; called by muse, mutect2, varscan2
- VPS35L | c.2771G>A p.G924D | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs922750409, COSV99221525; called by muse, mutect2, varscan2
- VSIG1 | c.1102T>C p.S368P | Missense Mutation (SNP) | VAF 109/537 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771887652; called by muse, mutect2, varscan2
- VSIR | c.856del p.L286Cfs*51 | Frame Shift Del (DEL) | VAF 107/515 reads (21%) | catalogued as rs752718137, COSV56484595; called by mutect2, pindel, varscan2
- WBP11 | c.912A>G p.S304= | Splice Region (SNP) | VAF 11/119 reads (9%) | catalogued as rs1181285488, COSV53764541; called by muse, mutect2
- WDR54 | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 86/381 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99270003; called by muse, mutect2, varscan2
- WDR81 | c.152dup p.T52Hfs*75 | Frame Shift Ins (INS) | VAF 120/632 reads (19%) | catalogued as rs1475024973; called by mutect2, varscan2
- WIZ | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 90/411 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as rs914963099; called by muse, mutect2, varscan2
- WNK1 | c.3698C>T p.A1233V (on ENST00000315939 / NM_018979.4; = p.A986V on NM_014823.3) | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs772922134, COSV60046628; ClinVar: benign; called by muse, mutect2, varscan2
- WNK2 | c.2423C>T p.A808V | Missense Mutation (SNP) | VAF 46/722 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs577942921, COSV52949581; called by muse, mutect2
- WNT1 | c.506del p.G169Afs*30 | Frame Shift Del (DEL) | VAF 128/691 reads (19%) | catalogued as COSV53295493; called by pindel, varscan2
- WNT3A | c.981C>G p.C327W | Missense Mutation (SNP) | VAF 34/666 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52734441; called by muse, mutect2
- WTIP | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 68/356 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as rs990099101; called by muse, mutect2, varscan2
- XAB2 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 120/463 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104381724; called by muse, mutect2, varscan2
- XKR5 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 81/499 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as COSV68398628; called by muse, mutect2, varscan2
- XRCC2 | c.801dup p.H268Tfs*11 | Frame Shift Ins (INS) | VAF 20/142 reads (14%) | catalogued as rs759063323; called by mutect2, varscan2
- YIF1A | c.285dup p.A96Cfs*30 | Frame Shift Ins (INS) | VAF 46/202 reads (23%) | catalogued as rs752032166; called by mutect2, varscan2
- Z83844.2 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 81/412 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs748020625; called by muse, mutect2, varscan2
- ZBTB46 | c.1320C>G p.H440Q | Missense Mutation (SNP) | VAF 110/522 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55513768; called by muse, mutect2, varscan2
- ZBTB47 | c.1276del p.A426Pfs*3 | Frame Shift Del (DEL) | VAF 134/674 reads (20%) | catalogued as rs1344689539; called by mutect2, pindel, varscan2
- ZC3H15 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as rs753545666, COSV61922514; called by muse, mutect2, varscan2
- ZC3H3 | c.2161G>A p.V721M | Missense Mutation (SNP) | VAF 87/527 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1373316052; called by muse, mutect2, varscan2
- ZFHX3 | c.6347C>T p.P2116L | Missense Mutation (SNP) | VAF 44/565 reads (8%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.492); catalogued as rs749013644, COSV104391232; called by muse, mutect2
- ZFP64 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 77/364 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775076590, COSV53797573; called by muse, mutect2, varscan2
- ZFYVE19 | c.1193G>A p.R398H (on ENST00000355341 / NM_001077268.2; = p.R388H on NM_032850.5) | Missense Mutation (SNP) | VAF 73/390 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs771942652; called by muse, mutect2, varscan2
- ZMYND8 | c.529G>A p.V177I (on ENST00000311275 / NM_001363741.2; = p.V197I on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); catalogued as COSV53695994; called by muse, mutect2, varscan2
- ZNF143 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.885); catalogued as rs756778809, COSV55179128; called by muse, mutect2, varscan2
- ZNF174 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 73/318 reads (23%) | catalogued as COSV51904187; called by muse, mutect2, varscan2
- ZNF235 | c.2201C>T p.T734I | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs1306698151; called by muse, mutect2, varscan2
- ZNF250 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs140313147; called by muse, mutect2, varscan2
- ZNF284 | c.1315A>G p.K439E | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as rs780799143; called by muse, mutect2, varscan2
- ZNF341 | c.2231G>A p.R744Q (on ENST00000375200 / NM_001282935.1; = p.R737Q on NM_032819.4) | Missense Mutation (SNP) | VAF 163/656 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as rs143443426, COSV100678050; called by muse, mutect2, varscan2
- ZNF408 | c.1942A>G p.T648A | Missense Mutation (SNP) | VAF 100/483 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs775032919; called by muse, mutect2, varscan2
- ZNF469 | c.3431G>A p.R1144H (on ENST00000437464; = p.R1172H on NM_001367624.2) | Missense Mutation (SNP) | VAF 159/619 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV71258246; called by muse, mutect2, varscan2
- ZNF48 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 116/582 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as rs1042078879; called by muse, mutect2, varscan2
- ZNF500 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 110/569 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs991739831; called by muse, mutect2, varscan2
- ZNF528 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as rs1308374456; called by muse, mutect2, varscan2
- ZNF558 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs781969585; called by muse, mutect2, varscan2
- ZNF608 | c.3526A>G p.K1176E | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.453); catalogued as COSV60437844; called by muse, mutect2, varscan2
- ZNF689 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs771627528; called by muse, mutect2, varscan2
- ZNF696 | c.448del p.E150Rfs*211 | Frame Shift Del (DEL) | VAF 116/868 reads (13%) | catalogued as COSV100350505; called by mutect2, pindel, varscan2
- ZNF710 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 63/373 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149111907; called by muse, mutect2, varscan2
- ZNF764 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 134/619 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs978901229; called by muse, mutect2, varscan2
- ZNF787 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 127/635 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1273033477, COSV99555331; called by muse, mutect2, varscan2
- ZNF827 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1463205644, COSV65231040; called by muse, mutect2, varscan2
- ZNF835 | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 91/471 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV73379547; called by muse, mutect2, varscan2
- ZNF835 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 139/577 reads (24%) | catalogued as rs1337645295, COSV101606340; called by muse, mutect2, varscan2
- ZNF862 | c.249del p.K83Nfs*52 | Frame Shift Del (DEL) | VAF 36/196 reads (18%) | catalogued as rs755241977; called by mutect2, pindel, varscan2
- ZSCAN21 | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 62/607 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs746058668; called by muse, mutect2, varscan2
- ZSWIM4 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 88/425 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs746661524, COSV54324645; called by muse, mutect2, varscan2
- ZSWIM9 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs1297775208; called by muse, mutect2, varscan2
- AATK | c.3593_3595dup p.V1198dup (on ENST00000326724 / NM_001080395.3; = p.V1095dup on NM_004920.2) | In Frame Ins (INS) | VAF 104/504 reads (21%) | called by mutect2, varscan2
- ABCA2 | c.5719C>A p.L1907I (on ENST00000614293; = p.L1877I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/370 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.074); called by mutect2, varscan2
- ABCA5 | c.3975del p.G1326Efs*4 | Frame Shift Del (DEL) | VAF 20/105 reads (19%) | called by mutect2, pindel, varscan2
- ABCA8 | c.2180G>A p.S727N | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCC11 | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ABCC12 | c.1914dup p.K639Efs*5 | Frame Shift Ins (INS) | VAF 95/489 reads (19%) | called by mutect2, pindel, varscan2
- ABCC5 | c.2463dup p.A822Sfs*82 | Frame Shift Ins (INS) | VAF 22/134 reads (16%) | called by pindel, varscan2
- ABCD1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 173/812 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ABCG8 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC100868.1 | c.1494del p.A499Pfs*18 | Frame Shift Del (DEL) | VAF 25/183 reads (14%) | called by mutect2, varscan2
- ADA2 | c.1214T>C p.I405T (on ENST00000262607; = p.I164T on NM_177405.3) | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- ADAMTS3 | c.968dup p.N324Kfs*20 | Frame Shift Ins (INS) | VAF 35/212 reads (17%) | called by mutect2, pindel, varscan2
- ADAMTS8 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 112/602 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADAR | c.108dup p.S37Qfs*2 | Frame Shift Ins (INS) | VAF 54/315 reads (17%) | called by mutect2, pindel, varscan2
- ADCY5 | c.889C>A p.H297N | Missense Mutation (SNP) | VAF 119/593 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADCYAP1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 120/494 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, varscan2
- AFAP1L1 | c.967G>T p.G323* | Nonsense Mutation (SNP) | VAF 82/379 reads (22%) | called by muse, mutect2, varscan2
- AFAP1L1 | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AFF2 | c.3071C>A p.S1024Y | Missense Mutation (SNP) | VAF 92/409 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- AFF3 | c.1323C>G p.S441R | Missense Mutation (SNP) | VAF 71/557 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- AGBL2 | c.184dup p.E62Gfs*4 | Frame Shift Ins (INS) | VAF 46/259 reads (18%) | called by mutect2, pindel, varscan2
- AGBL3 | c.73A>G p.M25V | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AGR3 | c.172del p.S58Vfs*5 | Frame Shift Del (DEL) | VAF 30/186 reads (16%) | called by mutect2, pindel, varscan2
- AGTPBP1 | c.3205del p.C1069Afs*2 (on ENST00000357081 / NM_001330701.2; = p.C1029Afs*2 on NM_015239.2) | Frame Shift Del (DEL) | VAF 42/244 reads (17%) | called by mutect2, pindel, varscan2
- AKAP11 | c.748A>T p.T250S | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKAP9 | c.3616_3617del p.L1206Mfs*6 | Frame Shift Del (DEL) | VAF 19/103 reads (18%) | called by mutect2, pindel, varscan2
- AL354761.1 | c.56del p.G19Vfs*43 | Frame Shift Del (DEL) | VAF 58/460 reads (13%) | called by pindel, varscan2
- ALDH1L1 | c.1244A>C p.K415T | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ALDH3A1 | c.1315C>A p.L439M | Missense Mutation (SNP) | VAF 84/414 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- AMBRA1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ANGPT4 | c.390del p.M131Cfs*2 | Frame Shift Del (DEL) | VAF 50/492 reads (10%) | called by mutect2, pindel
- ANK3 | c.7727G>T p.R2576M | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKAR | c.2084del p.N695Ifs*12 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, varscan2
- ANKFY1 | c.1099G>T p.G367W | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AOC3 | c.568dup p.Q190Pfs*66 | Frame Shift Ins (INS) | VAF 97/442 reads (22%) | called by mutect2, pindel, varscan2
- AP3D1 | c.1334C>A p.A445D | Missense Mutation (SNP) | VAF 66/470 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, varscan2
- APBB1 | c.1647dup p.N550Efs*6 | Frame Shift Ins (INS) | VAF 51/242 reads (21%) | called by mutect2, pindel, varscan2
- APBB1IP | c.1528C>A p.H510N | Missense Mutation (SNP) | VAF 126/514 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- APOA4 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 84/389 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- APOLD1 | c.580C>A p.L194M (on ENST00000326765 / NM_001130415.2; = p.L163M on NM_030817.3) | Missense Mutation (SNP) | VAF 93/456 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ARHGAP12 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ARHGEF25 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 76/342 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID3C | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 66/861 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- ARID5A | c.1433C>A p.P478H | Missense Mutation (SNP) | VAF 132/589 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ARSI | c.917del p.G306Afs*21 | Frame Shift Del (DEL) | VAF 104/523 reads (20%) | called by mutect2, pindel, varscan2
- ARSI | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 103/481 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASAH1 | c.173+1G>A p.X58_splice | Splice Site (SNP) | VAF 26/269 reads (10%) | called by muse, mutect2
- ASAP2 | c.1037C>A p.P346H | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ASIC3 | c.755A>G p.Q252R | Missense Mutation (SNP) | VAF 85/453 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ASPM | c.2071del p.Y691Mfs*17 | Frame Shift Del (DEL) | VAF 26/197 reads (13%) | called by mutect2, pindel, varscan2
- ATG16L2 | c.1184T>G p.V395G | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- ATIC | c.188dup p.R64Tfs*17 | Frame Shift Ins (INS) | VAF 47/261 reads (18%) | called by mutect2, pindel, varscan2
- ATP11C | c.767del p.N256Ifs*20 | Frame Shift Del (DEL) | VAF 19/198 reads (10%) | called by mutect2, pindel
- ATP12A | c.2183C>A p.A728D | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP13A4 | c.68T>C p.F23S | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP13A5 | c.3064G>A p.V1022M | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, varscan2
- ATP2B3 | c.1175T>A p.I392N | Missense Mutation (SNP) | VAF 87/465 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- AURKB | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 68/285 reads (24%) | called by muse, mutect2, varscan2
- BACE1 | c.845A>G p.N282S | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- BCAN | c.2711del p.P904Lfs*39 | Frame Shift Del (DEL) | VAF 84/460 reads (18%) | called by mutect2, pindel, varscan2
- BCHE | c.1778C>T p.T593I | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BCKDK | c.1042del p.L348Sfs*156 | Frame Shift Del (DEL) | VAF 111/501 reads (22%) | called by mutect2, pindel, varscan2
- BCORL1 | c.2238dup p.K747Qfs*9 | Frame Shift Ins (INS) | VAF 92/519 reads (18%) | called by mutect2, pindel, varscan2
- BEST1 | c.112A>T p.I38F | Missense Mutation (SNP) | VAF 70/311 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- BICRAL | c.1010A>T p.H337L | Missense Mutation (SNP) | VAF 25/358 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.198); called by muse, mutect2
- BMP1 | c.1310del p.G437Vfs*3 | Frame Shift Del (DEL) | VAF 68/370 reads (18%) | called by mutect2, pindel, varscan2
1,191 further variants in this file (698 protein-altering or splice-affecting, 410 silent, 83 other) are not listed here.
